CCDI case PBCVCT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/c206e4eb-b039-4a70-a99a-664bb7702c4a

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E0HQR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0HR2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
